Somatic mutation profile of tumor specimen 0DD3NH from CCDI case PBBNDD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.3 years (1,209 days).
Specimen 0DD3NH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db469a83-35dc-4da3-95be-dac1c4c878e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DD3NJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3619d5e2-b542-4747-8ac0-36c90b1ab5a4

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPC1 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 191/519 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.283); catalogued as rs146133433; called by muse, mutect2, varscan2
- CD34 | c.108C>T p.N36= | Silent (SNP) | VAF 24/362 reads (7%) | catalogued as rs764339451; called by muse, mutect2
- MT3 | c.*98C>A | 3'UTR (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
